Somatic mutation profile of tumor specimen TCGA-EK-A3GN-01A (aliquot TCGA-EK-A3GN-01A-11D-A20U-09) from TCGA case TCGA-EK-A3GN, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 47.7 years (17,425 days).
Specimen TCGA-EK-A3GN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 652107f4-d6ec-4e0a-84e9-ef59631ef9b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A3GN-10A (Blood Derived Normal), aliquot TCGA-EK-A3GN-10A-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/635c6257-90e6-4254-b50a-c9524036e24d

The open-access MAF lists 75 somatic variants for this specimen: 42 protein-altering or splice-affecting, 32 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 32, Nonsense Mutation 5, Splice Site 1, Splice Region 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F11 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.967); catalogued as rs763496524, CM035499, COSV53004761; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1099C>T p.R367* (on ENST00000281708 / NM_001349798.2; = p.R287* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 43/68 reads (63%) | hotspot (GDC flag); catalogued as COSV55891887; called by muse, mutect2, varscan2
- AKAP8 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as COSV54101537; called by muse, mutect2, varscan2
- CACNA1H | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs758015873, COSV61985841; called by muse, mutect2, varscan2
- CCN1 | c.796A>T p.I266F | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV101486117, COSV71704291; called by muse, mutect2, varscan2
- CDH23 | c.8744G>T p.R2915L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV56452556; called by muse, mutect2, varscan2
- CHD7 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.354); catalogued as rs757689264, COSV71107751; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLK2 | c.399G>A p.S133= | Splice Region (SNP) | VAF 28/46 reads (61%) | catalogued as COSV62876375; called by muse, mutect2, varscan2
- CMYA5 | c.909G>C p.W303C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV71404551; called by muse, mutect2
- COL5A1 | c.3994G>A p.D1332N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV65666476; called by muse, mutect2, varscan2
- CREBZF | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV52629081; called by muse, mutect2, varscan2
- CSMD3 | c.8120G>A p.W2707* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV52126876; called by muse, mutect2
- CYP26C1 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs767103970, COSV53651953; called by muse, mutect2, varscan2
- EGFL7 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.761); catalogued as rs1304820249, COSV100452072, COSV58247170; called by muse, mutect2, varscan2
- EPB41 | c.1738A>T p.K580* (on ENST00000343067 / NM_001166005.2; = p.K371* on NM_004437.4) | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV58042400; called by muse, mutect2, varscan2
- ERN1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV70500870; called by muse, mutect2, varscan2
- EVC2 | c.2477G>A p.R826Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1436641687, COSV60389157; called by muse, mutect2, varscan2
- FOXD4L5 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV66240227; called by mutect2, varscan2
- GDF5 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as rs1382285816, COSV65500025; called by muse, mutect2, varscan2
- GJD2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs202150693, COSV51747514; called by muse, mutect2, varscan2
- H3C12 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV58152208, COSV58153585, COSV58154290; called by muse, mutect2, varscan2
- IRX5 | c.1238C>T p.T413M | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58058554, COSV58059382; called by muse, mutect2, varscan2
- KNDC1 | c.3964G>A p.V1322I | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as rs559717203, COSV58833055; called by muse, mutect2, varscan2
- MTIF2 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs188291557, COSV55050625; called by muse, mutect2, varscan2
- MTMR7 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.313); catalogued as COSV51663962; called by muse, mutect2, varscan2
- MYH7B | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV53417438; called by muse, mutect2, varscan2
- NIPBL | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.956); catalogued as COSV56945541; called by muse, mutect2
- NOX1 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.112); catalogued as rs192653247, COSV54193235; called by muse, mutect2, varscan2
- PEAR1 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs367928332; called by muse, mutect2, varscan2
- PHLPP2 | c.1961A>G p.N654S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62423254; called by muse, mutect2, varscan2
- RBM6 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.157); catalogued as COSV56480546; called by muse, mutect2, varscan2
- REEP6 | c.351C>A p.C117* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV52012631, COSV99278881; called by muse, mutect2, varscan2
- RPS6KA6 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV53117384, COSV99425247; called by muse, mutect2, varscan2
- SLC44A2 | c.312C>G p.F104L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59835531; called by muse, mutect2, varscan2
- SLITRK4 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.482); catalogued as COSV62023519; called by muse, mutect2, varscan2
- TEP1 | c.6796C>T p.Q2266* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV52989492; called by muse, mutect2, varscan2
- TRPC3 | c.1855G>C p.V619L (on ENST00000379645 / NM_001366479.2; = p.V546L on NM_003305.2) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.951); catalogued as COSV53372997; called by muse, mutect2, varscan2
- TTN | c.29296C>T p.R9766C (on ENST00000591111; = p.R8839C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | PolyPhen possibly damaging (0.862); catalogued as rs377714947, COSV59907052; called by muse, mutect2, varscan2
- VPS41 | c.1270A>G p.K424E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV59646785; called by muse, mutect2, varscan2
- XPR1 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.257); catalogued as COSV62554182; called by muse, mutect2, varscan2
- C1orf87 | c.1128-5_1130del p.X376_splice | Splice Site (DEL) | VAF 5/62 reads (8%) | called by mutect2, pindel
- GCHFR | c.253_*21del | Nonstop Mutation (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- ATP13A4 | c.522A>G p.E174= | Silent (SNP) | VAF 47/78 reads (60%) | catalogued as rs748191221, COSV55067102; called by muse, mutect2, varscan2
- ATP2C1 | c.792C>T p.L264= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100147081, COSV60759031; called by muse, mutect2, varscan2
- CASZ1 | c.1230C>T p.P410= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs1473164109, COSV100681249, COSV100682368; called by muse, mutect2, varscan2
- CCDC86 | c.708G>A p.P236= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs752289054, COSV57124655, COSV99920261; called by muse, mutect2, varscan2
- CIAO2A | c.90C>T p.P30= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV55538006; called by muse, mutect2, varscan2
- COL15A1 | c.4134C>T p.I1378= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs752114228, COSV66642124; called by muse, mutect2, varscan2
- CYP4F2 | c.858C>T p.F286= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs564383704, COSV50000298; called by muse, mutect2, varscan2
- ERN1 | c.393G>A p.L131= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV70500863; called by muse, mutect2, varscan2
- GPLD1 | c.1734C>T p.S578= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV57755061; called by muse, mutect2, varscan2
- GPR35 | c.33C>T p.S11= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs548753085, COSV60576673; called by mutect2, varscan2
- HAS1 | c.372G>A p.P124= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV55786558; called by muse, mutect2, varscan2
- ISL1 | c.363G>A p.A121= | Silent (SNP) | VAF 10/12 reads (83%) | catalogued as rs1340354591, COSV57932765; called by muse, mutect2, varscan2
- KIR2DL3 | c.432C>T p.S144= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as rs373149242; called by muse, mutect2, varscan2
- LMTK2 | c.4389G>A p.P1463= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs1198920791, COSV51992256; called by muse, mutect2, varscan2
- MRPL21 | c.39G>T p.L13= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV54820729; called by muse, mutect2
- OR1L4 | c.909G>A p.K303= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs757120919, COSV52339864; called by muse, mutect2
- ORMDL2 | c.255C>T p.H85= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as rs1472962883, COSV54477991; called by muse, mutect2, varscan2
- PCBP3 | c.609G>A p.P203= | Silent (SNP) | VAF 28/35 reads (80%) | catalogued as rs746894659, COSV68406377; called by muse, mutect2, varscan2
- PCDHGA5 | c.1452C>T p.N484= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs369080489; called by muse, mutect2, varscan2
- PKN1 | c.2043C>G p.L681= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV99466726; called by muse, mutect2, varscan2
- PTCH1 | c.3792C>T p.F1264= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs144312968; called by muse, mutect2, varscan2
- QARS1 | c.1428C>T p.V476= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV60274318; called by muse, mutect2, varscan2
- SEMA5A | c.975C>T p.S325= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as rs765586378, COSV66787115; called by muse, mutect2, varscan2
- SGSM1 | c.2838C>T p.C946= (on ENST00000400359 / NM_001039948.4; = p.C885= on NM_133454.3) | Silent (SNP) | VAF 32/47 reads (68%) | catalogued as rs577535941, COSV63082328; called by muse, mutect2, varscan2
- SRCIN1 | c.657G>A p.L219= (on ENST00000621492; = p.L185= on NM_025248.3) | Silent (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- TCAP | c.300C>T p.G100= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as rs187261074; ClinVar: likely benign; called by muse, mutect2, varscan2
- THBS3 | c.2545C>T p.L849= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV58362800; called by muse, mutect2, varscan2
- TRAIP | c.1167C>T p.V389= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV58913347; called by muse, mutect2, varscan2
- TRIM11 | c.642C>T p.G214= | Silent (SNP) | VAF 38/58 reads (66%) | catalogued as rs778207950, COSV52856690, COSV52860738; called by muse, mutect2, varscan2
- TRIM9 | c.1365C>T p.N455= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs777361081, COSV53614186; called by muse, mutect2, varscan2
- UBN2 | c.1482A>G p.L494= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs1395120687, COSV99944682; called by muse, mutect2, varscan2
- ZNF512B | c.1206G>A p.L402= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs1259143547, COSV53867033; called by muse, mutect2, varscan2
- LAMA3 | c.4998+1406C>T | Intron (SNP) | VAF 19/56 reads (34%) | catalogued as rs1389851824, COSV52531536; called by muse, mutect2, varscan2
